Gene-level copy-number profile of tumor specimen TCGA-55-6978-01A from TCGA case TCGA-55-6978, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-55-6978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7ee802b4-410c-4c77-93bb-16e5ecbbfc14.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6978-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db5ba10e-3287-4543-a6fd-88f2f84a2e10

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,181; copy number 2: 42,437; copy number 3: 1,869; copy number 4: 388; copy number 5: 708; copy number 6: 152; copy number 7: 41; copy number 9: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6978-01A-11D-1943-01): tumor purity 0.26, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 939 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:102,813,230–103,074,843, 1 gene, copy number 6 (within-gene range 4–6): FBXL13.
- chr7:102,857,450–117,715,971, 208 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr7:119,495,024–121,309,842, 15 genes, copy number 7: LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1.
- chr8:79,520,145–80,543,104, 28 genes, copy number 5: AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4.
- chr19:31,655,356–32,184,504, 7 genes, copy number 6: RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1.
- chr19:32,597,006–37,304,395, 229 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:50,758,382–51,442,650, 73 genes, copy number 5 (broad region; genes not listed).
- chr19:52,797,408–52,857,600, 1 gene, copy number 5 (within-gene range 1–5): ZNF28.
- chr19:52,838,010–57,624,724, 377 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
